Somatic mutation profile of tumor specimen CDDP-ABJH-TTP1-H (aliquot CDDP-ABJH-TTP1-H-1-0-D-A500-36) from CDDP_EAGLE case CDDP-ABJH, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 54 years.
Specimen CDDP-ABJH-TTP1-H: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e84e8d5a-b68d-49b1-8760-63318660161f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ABJH-NB1-A (Blood Derived Normal), aliquot CDDP-ABJH-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63ef9a5a-24bb-437a-8f16-610382331c75

The open-access MAF lists 200 somatic variants for this specimen: 145 protein-altering or splice-affecting, 33 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 128, Silent 33, Intron 11, Nonsense Mutation 9, Splice Site 5, RNA 5, Splice Region 2, 3'UTR 2, 5'Flank 1, IGR 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 35/393 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ABCA7 | c.5686G>C p.G1896R | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776465510, COSV54032989; called by mutect2, varscan2
- ACTN2 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 16/281 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63976020; called by muse, mutect2
- ALDH8A1 | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 17/217 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs142480439, COSV55642909; called by muse, mutect2
- AQP12A | c.124-4G>A | Splice Region (SNP) | VAF 29/500 reads (6%) | catalogued as rs1326103201; called by muse, mutect2
- ATM | c.3250C>G p.Q1084E | Missense Mutation (SNP) | VAF 15/427 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as rs1386063673, COSV53732282; called by muse, mutect2
- BRINP1 | c.1819C>G p.R607G | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV99776336; called by muse, mutect2
- C10orf71 | c.3116C>A p.P1039H | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs979749435; called by muse, mutect2
- CHST15 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.046); catalogued as COSV60566336; called by muse, mutect2
- CNTNAP2 | c.2956G>C p.G986R | Missense Mutation (SNP) | VAF 26/448 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62168175; called by muse, mutect2
- CPS1 | c.2107C>A p.L703I | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1282294506; called by muse, mutect2
- CSMD3 | c.9767G>T p.S3256I (on ENST00000297405 / NM_001363185.1; = p.S3087I on NM_052900.3) | Missense Mutation (SNP) | VAF 25/440 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs752180249, COSV52107735, COSV99833094; called by muse, mutect2
- DNAH8 | c.9805G>C p.G3269R | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59430175; called by muse, mutect2
- DOCK7 | c.2833C>G p.P945A | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV52006312; called by muse, mutect2
- ENPP1 | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 26/513 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62936482; called by muse, mutect2
- FLG2 | c.4570C>T p.Q1524* | Nonsense Mutation (SNP) | VAF 26/436 reads (6%) | catalogued as rs148445702; called by muse, mutect2
- GPR83 | c.513G>T p.Q171H | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV54717591; called by muse, mutect2
- HNF4A | c.800G>T p.R267L | Missense Mutation (SNP) | VAF 18/393 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); catalogued as CM125274, COSV57379967; called by muse, mutect2
- IL36G | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.201); catalogued as COSV99381272; called by muse, mutect2
- IL4R | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 14/281 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV50172237; called by muse, mutect2
- KRT75 | c.571A>T p.T191S | Missense Mutation (SNP) | VAF 17/353 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.088); catalogued as COSV52874459; called by muse, mutect2
- MIER2 | c.850G>T p.A284S | Missense Mutation (SNP) | VAF 15/232 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53395647; called by muse, mutect2
- MYH9 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 18/458 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53392471, COSV53392490; called by muse, mutect2
- OR5F1 | c.498G>T p.L166F | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV53548738; called by muse, mutect2
- PCDHA9 | c.1455G>T p.Q485H | Missense Mutation (SNP) | VAF 38/936 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); catalogued as COSV65323298; called by muse, mutect2
- PCDHGB2 | c.1577G>T p.R526L | Missense Mutation (SNP) | VAF 14/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54025302; called by muse, mutect2
- PHF3 | c.505G>T p.A169S | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV50345138; called by muse, mutect2
- PKDREJ | c.2009C>G p.P670R | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53546751; called by muse, mutect2
- PNMA5 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); catalogued as rs782553555, COSV62625985; called by muse, mutect2, varscan2
- RAB6D | c.476C>A p.A159D | Missense Mutation (SNP) | VAF 28/521 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.352); catalogued as rs751631052; called by muse, mutect2
- RIMBP2 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.175); catalogued as rs1370311081; called by muse, mutect2
- SF3B2 | c.2128G>T p.E710* | Nonsense Mutation (SNP) | VAF 8/118 reads (7%) | catalogued as COSV59430491; called by muse, mutect2
- SHC2 | c.524G>T p.R175L | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52744137; called by muse, mutect2
- SLITRK4 | c.1634G>T p.W545L | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100567296; called by muse, mutect2, varscan2
- SPTAN1 | c.5250G>T p.K1750N | Missense Mutation (SNP) | VAF 26/460 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV63987676; called by muse, mutect2
- TCF20 | c.3578G>T p.R1193L | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV59496741; called by muse, mutect2
- TG | c.3458A>G p.K1153R | Missense Mutation (SNP) | VAF 38/373 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs1468342016; called by muse, mutect2
- TMEM239 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); catalogued as rs1220786707; called by muse, mutect2
- TUBGCP3 | c.2408G>T p.R803L | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.708); catalogued as COSV56184561; called by muse, mutect2
- USH2A | c.4226A>T p.Q1409L | Missense Mutation (SNP) | VAF 12/396 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.182); catalogued as COSV100241975; called by muse, mutect2
- XPNPEP3 | c.754A>G p.I252V | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs771218448; called by muse, mutect2
- ZNF208 | c.2593G>T p.E865* | Nonsense Mutation (SNP) | VAF 16/338 reads (5%) | catalogued as rs918741057; called by muse, mutect2
- AK5 | c.580C>A p.P194T (on ENST00000354567 / NM_174858.3; = p.P168T on NM_012093.4) | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ALOX15B | c.2000C>A p.P667H | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AQP12A | c.124-3G>T | Splice Region (SNP) | VAF 28/500 reads (6%) | called by muse, mutect2
- ASH1L | c.931G>T p.G311C | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2
- ATP1A3 | c.607C>A p.P203T (on ENST00000545399 / NM_001256214.2; = p.P190T on NM_152296.5) | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BMP1 | c.2707G>T p.E903* | Nonsense Mutation (SNP) | VAF 17/345 reads (5%) | called by muse, mutect2
- BTAF1 | c.2387T>G p.V796G | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- CAPRIN2 | c.421-1G>T p.X141_splice | Splice Site (SNP) | VAF 12/214 reads (6%) | called by muse, mutect2
- CEP170 | c.3292A>T p.T1098S | Missense Mutation (SNP) | VAF 15/226 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- CEP290 | c.898G>T p.D300Y | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFDP1 | c.869G>T p.R290L | Missense Mutation (SNP) | VAF 11/206 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2
- CLTCL1 | c.4068C>A p.H1356Q | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.924); called by muse, mutect2
- CLVS2 | c.188T>A p.F63Y | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.166); called by muse, mutect2
- CMTR1 | c.338G>T p.R113L | Missense Mutation (SNP) | VAF 17/272 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.187); called by muse, mutect2
- CNTN5 | c.1976T>A p.V659E | Missense Mutation (SNP) | VAF 9/201 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- CSMD3 | c.1952G>T p.G651V (on ENST00000297405 / NM_001363185.1; = p.G547V on NM_052900.3) | Missense Mutation (SNP) | VAF 21/336 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CYLC1 | c.499C>A p.H167N | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DENND2C | c.213G>C p.L71F | Missense Mutation (SNP) | VAF 23/491 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.202); called by muse, mutect2
- DIP2C | c.2941C>T p.Q981* | Nonsense Mutation (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- DMRT3 | c.1286C>A p.A429D | Missense Mutation (SNP) | VAF 14/201 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); called by muse, mutect2
- DYNC2H1 | c.5558+2T>A p.X1853_splice | Splice Site (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2, varscan2
- ENO1 | c.707A>T p.Y236F | Missense Mutation (SNP) | VAF 13/231 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.396); called by muse, mutect2
- FAT2 | c.5857C>A p.L1953M | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.549); called by muse, mutect2
- FBXO40 | c.1651C>A p.P551T | Missense Mutation (SNP) | VAF 14/343 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2
- FCRL6 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2
- FER1L6 | c.3453G>T p.Q1151H | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.258); called by muse, mutect2
- FGF13 | c.514G>T p.G172C | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FHOD3 | c.414G>T p.K138N | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- FLNC | c.7349C>T p.A2450V | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.05); called by muse, mutect2
- FSIP2 | c.10624C>A p.H3542N | Missense Mutation (SNP) | VAF 15/256 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- GABRA6 | c.1190T>A p.L397* | Nonsense Mutation (SNP) | VAF 13/301 reads (4%) | called by muse, mutect2
- GGTLC2 | c.299A>T p.Q100L | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2
- GPR78 | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.212); called by muse, mutect2
- GRB10 | c.662-2A>G p.X221_splice | Splice Site (SNP) | VAF 25/348 reads (7%) | called by muse, mutect2
- GRIK3 | c.1652A>G p.N551S | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.052); called by muse, mutect2
- GRM5 | c.1879C>A p.L627M | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.752); called by muse, mutect2
- GRM8 | c.1366G>T p.G456C | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GTF3C1 | c.3210G>T p.E1070D | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- HDAC4 | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 18/340 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- HERC2 | c.14408G>T p.G4803V | Missense Mutation (SNP) | VAF 16/340 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2
- HIVEP2 | c.1616C>A p.P539H | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.887); called by muse, mutect2
- HMGXB4 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2
- IGKV1-12 | c.55+2T>A p.X19_splice | Splice Site (SNP) | VAF 42/1047 reads (4%) | called by muse, mutect2
- IL22 | c.127G>C p.D43H | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.146); called by muse, mutect2
- ILF3 | c.855G>A p.M285I | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.1); called by muse, mutect2
- ISL2 | c.940G>T p.D314Y | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); called by muse, mutect2
- KAT5 | c.1312C>G p.Q438E | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.379); called by muse, mutect2
- KATNIP | c.3143G>T p.W1048L | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNK15 | c.452G>T p.W151L | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNQ1 | c.1939T>A p.S647T | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- KIF21A | c.2158G>T p.E720* (on ENST00000361418 / NM_001378440.1; = p.E707* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/241 reads (7%) | called by muse, mutect2
- KRT16 | c.193G>T p.G65W | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- LAMC3 | c.4132A>T p.K1378* | Nonsense Mutation (SNP) | VAF 34/492 reads (7%) | called by muse, mutect2
- LAYN | c.265C>A p.L89M (on ENST00000375615 / NM_001258390.1; = p.L81M on NM_178834.5) | Missense Mutation (SNP) | VAF 15/369 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- LDB1 | c.424G>T p.V142F (on ENST00000425280 / NM_001321612.2; = p.V106F on NM_003893.5) | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.361); called by muse, mutect2
- M1AP | c.874A>G p.T292A | Missense Mutation (SNP) | VAF 10/276 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.606); called by muse, mutect2
- MATN2 | c.1361G>T p.C454F | Missense Mutation (SNP) | VAF 11/266 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MRAP2 | c.199C>A p.L67M | Missense Mutation (SNP) | VAF 12/314 reads (4%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); called by muse, mutect2
- MRO | c.210A>T p.R70S | Missense Mutation (SNP) | VAF 10/207 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.389); called by muse, mutect2
- NAV3 | c.6176G>A p.G2059D (on ENST00000397909 / NM_001024383.2; = p.G2037D on NM_014903.6) | Missense Mutation (SNP) | VAF 18/374 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NBEA | c.8822A>T p.E2941V | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- NDFIP2 | c.689A>T p.D230V | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NLRP12 | c.404G>T p.R135M | Missense Mutation (SNP) | VAF 32/555 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2
- NMU | c.401T>A p.L134Q | Missense Mutation (SNP) | VAF 17/383 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NPAP1 | c.1292A>T p.D431V | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.629); called by muse, mutect2
- OR51F1 | c.284G>A p.W95* | Nonsense Mutation (SNP) | VAF 13/321 reads (4%) | called by muse, mutect2
- OR52D1 | c.702T>A p.H234Q | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2
- OR8J1 | c.192A>T p.Q64H | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2
- OTUD1 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.133); called by muse, varscan2
- PCDHA5 | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 20/596 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); called by muse, mutect2
- PNPLA5 | c.922del p.E308Sfs*11 | Frame Shift Del (DEL) | VAF 10/94 reads (11%) | called by mutect2, pindel
- POP1 | c.1416G>T p.K472N | Missense Mutation (SNP) | VAF 20/368 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2
- POU3F4 | c.172G>T p.V58L | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PPIP5K1 | c.3365C>T p.A1122V (on ENST00000396923; = p.A1097V on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/255 reads (5%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2
- PRIMPOL | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- PSPC1 | c.581G>A p.R194K | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.114); called by muse, mutect2
- PWP1 | c.1083T>A p.S361R | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- RAD21L1 | c.1124G>C p.G375A | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.006); called by muse, mutect2
- RALGAPA1 | c.955C>A p.H319N | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2
- RBBP6 | c.3635A>T p.N1212I | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- RHPN1 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by muse, mutect2
- ROS1 | c.3112G>A p.E1038K | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.283); called by muse, mutect2
- SAMHD1 | c.862A>G p.K288E | Missense Mutation (SNP) | VAF 22/377 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.118); called by muse, mutect2
- SERPINA9 | c.553G>T p.G185W | Missense Mutation (SNP) | VAF 20/333 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SETBP1 | c.4568C>A p.P1523H | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.601); called by muse, varscan2
- SFSWAP | c.1548+1G>T p.X516_splice | Splice Site (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- SLC17A6 | c.1390G>A p.V464I | Missense Mutation (SNP) | VAF 7/200 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.562); called by muse, mutect2
- SLC2A2 | c.923T>G p.L308R | Missense Mutation (SNP) | VAF 13/401 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2
- SLC6A19 | c.1223C>G p.T408S | Missense Mutation (SNP) | VAF 30/247 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- SLC8A1 | c.2129C>G p.T710S | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.108); called by muse, mutect2
- SPATA13 | c.1532A>T p.D511V | Missense Mutation (SNP) | VAF 25/340 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- SPI1 | c.634C>G p.R212G | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- SPP1 | c.301G>T p.D101Y (on ENST00000395080 / NM_001040058.2; = p.D87Y on NM_000582.2) | Missense Mutation (SNP) | VAF 11/247 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- SPTA1 | c.4912G>T p.D1638Y | Missense Mutation (SNP) | VAF 26/400 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- STEAP2 | c.313A>G p.R105G | Missense Mutation (SNP) | VAF 8/187 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.122); called by muse, mutect2
- TARBP1 | c.1428G>C p.K476N | Missense Mutation (SNP) | VAF 7/177 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.273); called by muse, mutect2
- THSD7B | c.2832G>T p.R944S | Missense Mutation (SNP) | VAF 10/257 reads (4%) | SIFT tolerated (0.79); PolyPhen benign (0.012); called by muse, mutect2
- TLL2 | c.317G>T p.S106I | Missense Mutation (SNP) | VAF 8/165 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2
- TNKS1BP1 | c.679A>G p.K227E | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2
- TRPA1 | c.762G>C p.M254I | Missense Mutation (SNP) | VAF 14/245 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.291); called by muse, mutect2
- ZFHX3 | c.2140G>T p.A714S | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZIC1 | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 13/240 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.185); called by muse, mutect2
- ZNF208 | c.938A>T p.Y313F | Missense Mutation (SNP) | VAF 17/259 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); called by muse, mutect2
- ABCA2 | c.978C>G p.V326= (on ENST00000614293; = p.V296= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/208 reads (4%) | called by muse, mutect2
- ABCC4 | c.3405G>A p.L1135= | Silent (SNP) | VAF 12/307 reads (4%) | called by muse, mutect2
- AHNAK | c.10716G>T p.L3572= | Silent (SNP) | VAF 12/286 reads (4%) | called by muse, mutect2
- CSHL1 | c.411G>T p.S137= (on ENST00000309894 / NM_022581.3; = p.S43= on NM_001318.4) | Silent (SNP) | VAF 24/348 reads (7%) | called by muse, mutect2
- CUZD1 | c.1752A>T p.V584= | Silent (SNP) | VAF 14/296 reads (5%) | called by muse, mutect2
- EYS | c.5397T>A p.T1799= | Silent (SNP) | VAF 18/311 reads (6%) | called by muse, mutect2
- HGH1 | c.189G>A p.A63= | Silent (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- IGKV1-9 | c.27C>A p.L9= | Silent (SNP) | VAF 20/258 reads (8%) | called by muse, mutect2
- IL21R | c.1362A>T p.A454= | Silent (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- IQSEC3 | c.946C>A p.R316= (on ENST00000538872 / NM_001170738.2; = p.R13= on NM_015232.1) | Silent (SNP) | VAF 9/119 reads (8%) | catalogued as COSV58285146, COSV58290179; called by muse, mutect2
- ISG20 | c.525C>T p.P175= | Silent (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- MAP1B | c.33G>A p.P11= | Silent (SNP) | VAF 13/99 reads (13%) | called by muse, mutect2, varscan2
- NPR1 | c.2697C>A p.T899= | Silent (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- NWD2 | c.4311C>A p.T1437= | Silent (SNP) | VAF 12/222 reads (5%) | called by muse, mutect2
- OR10AG1 | c.588G>T p.V196= | Silent (SNP) | VAF 10/244 reads (4%) | called by muse, mutect2
- OR2B3 | c.700C>A p.R234= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV65850780, COSV65851115; called by muse, mutect2
- OR4D9 | c.432C>T p.L144= | Silent (SNP) | VAF 7/100 reads (7%) | catalogued as rs1274724699; called by muse, mutect2
- OR6A2 | c.522T>C p.C174= | Silent (SNP) | VAF 18/349 reads (5%) | called by muse, mutect2
- OR7E24 | c.153C>A p.S51= | Silent (SNP) | VAF 16/296 reads (5%) | catalogued as rs1193060188, COSV101509688, COSV71702121; called by muse, mutect2
- PCDH11X | c.4020C>A p.P1340= | Silent (SNP) | VAF 28/197 reads (14%) | catalogued as COSV53476764; called by muse, mutect2, varscan2
- PCDHGA8 | c.675A>T p.T225= | Silent (SNP) | VAF 10/222 reads (5%) | called by muse, mutect2
- PRSS57 | c.525G>T p.L175= | Silent (SNP) | VAF 10/186 reads (5%) | called by muse, mutect2
- SFT2D3 | c.291C>T p.Y97= | Silent (SNP) | VAF 18/194 reads (9%) | called by muse, mutect2
- SPATA31A1 | c.858T>A p.T286= | Silent (SNP) | VAF 40/844 reads (5%) | called by muse, mutect2
- TIAM2 | c.918C>A p.A306= | Silent (SNP) | VAF 17/426 reads (4%) | called by muse, mutect2
- TMEM255B | c.831A>T p.P277= | Silent (SNP) | VAF 21/296 reads (7%) | called by muse, mutect2
- TNIK | c.3831C>T p.L1277= | Silent (SNP) | VAF 18/345 reads (5%) | called by muse, mutect2
- TSPAN8 | c.604T>C p.L202= | Silent (SNP) | VAF 7/61 reads (11%) | called by mutect2, varscan2
- TUSC3 | c.813G>T p.G271= | Silent (SNP) | VAF 16/338 reads (5%) | catalogued as COSV65877537; called by muse, mutect2
- URB2 | c.2433C>T p.F811= | Silent (SNP) | VAF 9/141 reads (6%) | called by muse, mutect2
- WDR87 | c.3114G>T p.L1038= | Silent (SNP) | VAF 12/366 reads (3%) | called by muse, mutect2
- ZFP62 | c.2463C>T p.F821= (on ENST00000502412 / NM_001377944.1; = p.F788= on NM_152283.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 12/200 reads (6%) | called by muse, mutect2
- ZFYVE26 | c.5073G>T p.V1691= | Silent (SNP) | VAF 13/320 reads (4%) | called by muse, mutect2
- AC127029.3 | c.*30C>A | 3'UTR (SNP) | VAF 27/358 reads (8%) | called by muse, mutect2
- AGAP1 | c.674-20769C>T | Intron (SNP) | VAF 18/295 reads (6%) | called by muse, mutect2
- AL353804.6 | chrX:73826633 G>T | 3'Flank (SNP) | VAF 13/125 reads (10%) | called by muse, mutect2, varscan2
- ARID5A | c.313-86G>T | Intron (SNP) | VAF 15/254 reads (6%) | called by muse, mutect2
- CCDC42 | c.*56T>A | 3'UTR (SNP) | VAF 18/212 reads (8%) | called by muse, mutect2
- CEROX1 | n.2973G>T | RNA (SNP) | VAF 18/441 reads (4%) | called by muse, mutect2
- CNOT7 | c.118-362A>T | Intron (SNP) | VAF 10/270 reads (4%) | called by muse, mutect2
- COL6A2 | c.2462-2686C>A | Intron (SNP) | VAF 28/346 reads (8%) | catalogued as COSV55999206; called by muse, mutect2
- FAM197Y1 | n.268C>T | RNA (SNP) | VAF 50/374 reads (13%) | called by muse, mutect2, varscan2
- HLX | c.773-18G>T | Intron (SNP) | VAF 12/200 reads (6%) | called by muse, mutect2
- KCNJ5 | c.-10-33C>G | Intron (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- LHX9 | chr1:197916684 G>T | 5'Flank (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- LRRC37A6P | n.1459C>A | RNA (SNP) | VAF 18/308 reads (6%) | called by muse, mutect2
- NAV3 | c.2024-12642G>C | Intron (SNP) | VAF 10/183 reads (5%) | called by muse, mutect2
- SLC6A18 | c.-15G>A | 5'UTR (SNP) | VAF 27/194 reads (14%) | called by muse, mutect2
- SMARCC1 | c.1041-9A>G | Intron (SNP) | VAF 7/69 reads (10%) | catalogued as rs1350003265; called by muse, mutect2, varscan2
- SPATA31C2 | n.678C>A | RNA (SNP) | VAF 21/428 reads (5%) | called by muse, mutect2
- SSPOP | n.1963G>T | RNA (SNP) | VAF 12/204 reads (6%) | called by muse, mutect2
- TMEM51 | c.-267+14658A>T | Intron (SNP) | VAF 28/458 reads (6%) | catalogued as rs1246180836; called by muse, mutect2
- Unknown | chr2:111238216 G>T | IGR (SNP) | VAF 12/216 reads (6%) | called by muse, mutect2
- ZMAT4 | c.102+17036A>C | Intron (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- ZNF418 | c.6+1316G>T | Intron (SNP) | VAF 8/143 reads (6%) | called by muse, mutect2
